Somatic mutation profile of tumor specimen MMRF_1425_1_BM_CD138pos (aliquot MMRF_1425_1_BM_CD138pos_T1_KAS5U_L01598) from MMRF case MMRF_1425, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.9 years (27,357 days).
Specimen MMRF_1425_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b48eabe1-6102-48ad-be8c-b1112802b604.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1425_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1425_1_PB_Whole_C2_KAS5U_L01607; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec270791-79f2-4704-86af-812524dcabb0

The open-access MAF lists 99 somatic variants for this specimen: 40 protein-altering or splice-affecting, 13 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 19, Silent 13, Intron 13, 5'UTR 7, 3'Flank 3, 5'Flank 2, RNA 2, Splice Region 2, Translation Start Site 1, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 63/241 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGXT2 | c.1070C>G p.P357R | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749082205; called by muse, mutect2, varscan2
- ATP7A | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs1189996419; called by muse, mutect2, varscan2
- AXL | c.1421G>A p.R474Q (on ENST00000301178 / NM_021913.5; = p.R465Q on NM_001699.6) | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as rs545871181; called by muse, mutect2
- BRINP3 | c.1810C>T p.P604S | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (1); PolyPhen possibly damaging (0.637); catalogued as rs1306355384; called by muse, mutect2, varscan2
- C11orf40 | n.142G>A | Splice Region (SNP) | VAF 24/35 reads (69%) | catalogued as COSV56890552; called by muse, mutect2
- DACT2 | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1006173763; called by muse, mutect2, varscan2
- ECD | c.1132C>T p.L378F | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.501); catalogued as rs1308335631; called by muse, mutect2, varscan2
- GABRA5 | c.887C>T p.T296M | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748825379; called by muse, mutect2
- GRM4 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as rs763727042, COSV65213302; called by muse, mutect2, varscan2
- ITSN1 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs770995793; called by muse, mutect2, varscan2
- MACF1 | c.3602G>A p.R1201Q | Missense Mutation (SNP) | VAF 40/86 reads (47%) | catalogued as rs757376311, COSV58377760; called by muse, mutect2, varscan2
- MET | c.249G>T p.E83D | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as COSV59262514; called by muse, mutect2, varscan2
- PKD1L2 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as rs764963516; called by muse, mutect2, varscan2
- TBX20 | c.1331C>T p.T444M | Missense Mutation (SNP) | VAF 81/290 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs201217462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM177 | c.800A>T p.D267V | Missense Mutation (SNP) | VAF 95/166 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV55609282; called by muse, mutect2, varscan2
- ZNF835 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 22/315 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as COSV101606233, COSV73379348; called by muse, mutect2
- ZNF862 | c.2339G>A p.R780H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as rs367700175; called by muse, mutect2, varscan2
- ANKRD18A | c.1185A>T p.K395N | Missense Mutation (SNP) | VAF 60/283 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- BCL11B | c.642T>C p.G214= (on ENST00000357195 / NM_001282237.2; = p.G143= on NM_022898.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.9344G>T p.G3115V | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GGCT | c.458C>A p.P153Q | Missense Mutation (SNP) | VAF 24/443 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GIMAP8 | c.392T>G p.I131S | Missense Mutation (SNP) | VAF 124/201 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- H4C4 | c.137G>C p.R46P | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HCRTR2 | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.202); called by mutect2, varscan2
- HECW1 | c.91A>G p.S31G | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HSP90B1 | c.808_810del p.K270del | In Frame Del (DEL) | VAF 4/17 reads (24%) | called by mutect2, varscan2
- IDE | c.116A>G p.Y39C | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV2-70D | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, varscan2
- IRGQ | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KCNH2 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1109 | c.13219G>A p.A4407T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- METTL8 | c.781G>C p.G261R | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- N4BP2 | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PTK2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 101/462 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- RALY | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 113/225 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SHOC1 | c.3596_3598dup p.N1199dup | In Frame Ins (INS) | VAF 24/103 reads (23%) | called by mutect2, pindel, varscan2
- TMEM131 | c.3082C>G p.Q1028E | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- TYK2 | c.3092T>C p.L1031P | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF514 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BPIFB4 | c.774C>T p.N258= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs1488689709; called by muse, mutect2, varscan2
- CSMD2 | c.6123C>T p.S2041= | Silent (SNP) | VAF 49/116 reads (42%) | catalogued as rs149538328, COSV99585951; called by muse, mutect2, varscan2
- FRYL | c.2271C>T p.L757= | Silent (SNP) | VAF 38/76 reads (50%) | called by muse, mutect2, varscan2
- HAND1 | c.264T>C p.L88= | Silent (SNP) | VAF 70/107 reads (65%) | called by muse, mutect2, varscan2
- LTB | c.396C>T p.L132= | Silent (SNP) | VAF 28/114 reads (25%) | called by muse, mutect2, varscan2
- PARP8 | c.1974C>T p.N658= | Silent (SNP) | VAF 50/80 reads (63%) | called by muse, mutect2, varscan2
- PDCD7 | c.1026C>G p.A342= | Silent (SNP) | VAF 29/91 reads (32%) | called by muse, mutect2, varscan2
- PRKAG3 | c.666C>T p.N222= | Silent (SNP) | VAF 20/172 reads (12%) | catalogued as rs200735141, COSV52101464; called by muse, mutect2, varscan2
- PSMA3 | c.561C>T p.C187= | Silent (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- SDHA | c.114T>C p.D38= | Silent (SNP) | VAF 29/77 reads (38%) | called by muse, mutect2, varscan2
- SLC12A5 | c.738A>T p.A246= (on ENST00000454036 / NM_001134771.2; = p.A223= on NM_020708.5) | Silent (SNP) | VAF 42/77 reads (55%) | called by muse, mutect2, varscan2
- ZFAND2B | c.753G>A p.P251= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs562401510; called by muse, mutect2, varscan2
- ZFHX4 | c.2607G>A p.P869= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs763801174; called by muse, mutect2, varscan2
- AC114741.1 | n.145T>C | RNA (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- AKT1 | c.-163-509A>G | Intron (SNP) | VAF 108/238 reads (45%) | called by muse, mutect2, varscan2
- ANK2 | c.85-57379G>A | Intron (SNP) | VAF 13/28 reads (46%) | catalogued as rs770708276; called by muse, mutect2, varscan2
- AQP10 | c.707+186A>C | Intron (SNP) | VAF 122/279 reads (44%) | called by muse, mutect2, varscan2
- ARHGAP30 | c.-45_-38dup | 5'UTR (INS) | VAF 154/385 reads (40%) | called by mutect2, varscan2
- ASB16 | c.570-175A>T | Intron (SNP) | VAF 7/22 reads (32%) | called by muse, varscan2
- BMP6 | chr6:7881701 del GTGATTAATAAAGATTTCCTTTAAGGCAGAGGCTGGTCGAGATGCT | 3'UTR (DEL) | VAF 38/146 reads (26%) | called by mutect2, pindel
- BMPR1B | chr4:95157668 T>C | 3'Flank (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- CCDC88A | c.2855+13T>A | Intron (SNP) | VAF 25/90 reads (28%) | called by muse, mutect2, varscan2
- CELA3A | chr1:21998341 G>C | 5'Flank (SNP) | VAF 34/130 reads (26%) | called by muse, mutect2, varscan2
- CREBZF | c.*287+169C>G | Intron (SNP) | VAF 40/194 reads (21%) | called by muse, varscan2
- CRPPA | c.*254C>T | 3'UTR (SNP) | VAF 9/175 reads (5%) | called by muse, mutect2
- DHX8 | chr17:43526643 A>G | 3'Flank (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- DPP10 | c.*1280A>G | 3'UTR (SNP) | VAF 7/136 reads (5%) | called by muse, mutect2
- DUSP18 | c.*984T>C | 3'UTR (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- EGFR | c.*4941A>G | 3'UTR (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- FBXO32 | c.*2000T>G | 3'UTR (SNP) | VAF 22/124 reads (18%) | catalogued as rs1040636124; called by mutect2, varscan2
- GOLGA1 | c.*935G>A | 3'UTR (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- KIDINS220 | c.*1255A>T | 3'UTR (SNP) | VAF 49/124 reads (40%) | called by muse, mutect2, varscan2
- LACC1 | c.-1G>A | 5'UTR (SNP) | VAF 47/212 reads (22%) | called by muse, mutect2, varscan2
- LGR4 | c.*1267_*1268dup | 3'UTR (INS) | VAF 30/87 reads (34%) | called by mutect2, pindel, varscan2
- LINC02054 | n.2595-11364C>A | Intron (SNP) | VAF 23/98 reads (23%) | called by muse, mutect2, varscan2
- LONRF2 | c.*4829T>A | 3'UTR (SNP) | VAF 28/105 reads (27%) | called by muse, mutect2, varscan2
- LTB | c.209-31C>A | Intron (SNP) | VAF 32/77 reads (42%) | catalogued as rs560484795; called by muse, mutect2, varscan2
- LTB | c.163-154del | Intron (DEL) | VAF 61/180 reads (34%) | called by mutect2, pindel, varscan2
- LY6K | c.-342G>A | 5'UTR (SNP) | VAF 9/31 reads (29%) | catalogued as rs982184595; called by muse, mutect2, varscan2
- MALRD1 | c.4688-116C>A | Intron (SNP) | VAF 35/114 reads (31%) | called by muse, mutect2, varscan2
- MAML3 | c.468+18607C>T | Intron (SNP) | VAF 66/174 reads (38%) | called by muse, varscan2
- MASP1 | c.*417T>C | 3'UTR (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- MECP2 | c.*6972C>T | 3'UTR (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- MEGF10 | c.*1333C>A | 3'UTR (SNP) | VAF 34/140 reads (24%) | called by muse, mutect2, varscan2
- MFRP | chr11:119344978 G>C | 5'Flank (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- MPP4 | c.*18T>C | 3'UTR (SNP) | VAF 76/253 reads (30%) | called by muse, mutect2, varscan2
- PAK1 | c.836+95T>C | Intron (SNP) | VAF 52/132 reads (39%) | called by muse, mutect2
- RCC2 | chr1:17407652 A>T | 3'Flank (SNP) | VAF 79/278 reads (28%) | catalogued as rs1432920140; called by muse, varscan2
- RTL6 | c.-10T>C | 5'UTR (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- SLC6A10P | n.3764G>T | RNA (SNP) | VAF 30/106 reads (28%) | called by mutect2, varscan2
- TGFA | c.*366G>T | 3'UTR (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- TMEM127 | c.*2017C>G | 3'UTR (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- TMEM243 | c.-130G>A | 5'UTR (SNP) | VAF 29/133 reads (22%) | called by muse, mutect2, varscan2
- TNFRSF8 | c.-116G>A | 5'UTR (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- USP37 | c.*2553T>C | 3'UTR (SNP) | VAF 33/91 reads (36%) | called by muse, mutect2, varscan2
- UXS1 | c.-9C>A | 5'UTR (SNP) | VAF 6/38 reads (16%) | called by muse, varscan2
- YLPM1 | c.6111+754A>G | Intron (SNP) | VAF 32/108 reads (30%) | catalogued as rs1263118162; called by muse, mutect2, varscan2
- ZBTB4 | c.*2156_*2157insG | 3'UTR (INS) | VAF 56/138 reads (41%) | called by mutect2, pindel, varscan2
- ZNF429 | c.*12C>G | 3'UTR (SNP) | VAF 4/31 reads (13%) | catalogued as rs971955187; called by muse, mutect2
